Surgical pathology report (de-identified scan), TCGA case TCGA-DE-A0Y3, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of North Carolina, specimen TCGA-DE-A0Y3-01B (Primary Tumor).

[page 1 of 3]
Case Number :

1CD-0-3

Collection Date

Carcinoma, papillary thyroid 8260/3

Site: thyroid, NOS C73.9

2/18/11 *fw*

Surgical Pathology Report

Diagnosis:

A: Parathyroid, right inferior, biopsy

- One lymph node, negative for malignancy (0/1).
- Negative for parathyroid tissue.

B: Parathyroid, right superior, biopsy

- Benign normocellular parathyroid tissue.
- Negative for malignancy.

C: Parathyroid, left superior, biopsy

- Benign normocellular parathyroid tissue.
- Negative for malignancy.

D: Muscle, left cricoid thyroid, biopsy

- Metastatic papillary thyroid carcinoma present in muscle and soft tissue.
- Dystrophic calcifications

E: Lymph nodes, left neck, Levels 2-4, removal

- 1 of 16 lymph nodes positive for metastatic papillary thyroid carcinoma, 6 mm in greatest dimension, extracapsular extension present (1/16).

F: Lymph nodes, left neck, Level 6, reveal

- Three of six lymph nodes positive for metastatic papillary thyroid carcinoma, 6 mm in greatest dimension, extracapsular extension present (3/6).
- Benign normocellular parathyroid tissue.
- Ectopic thymic tissue, negative for malignancy.

G: Thyroid, total thyroidectomy

Histologic tumor type: papillary thyroid carcinoma

Tumor size (greatest dimension): 2.5 cm

Tumor growth pattern: invasive

Invasive properties:

Extra-thyroidal soft tissues: papillary thyroid carcinoma extends into surrounding skeletal muscle

Capsular: not identified

Lymphovascular: present

Blood vascular: not identified

Tumor multicentricity: There are two foci of papillary thyroid carcinoma present; the largest is in the left thyroid lobe measuring 2.5 cm and there is a small microscopic (1 mm in greatest diameter) focus in the mid right thyroid lobe.

Histologic assessment of surgical margins: Papillary thyroid carcinoma extends to the left anterior margin and is within 1 mm of the left posterior margin and extends into the isthmus. The anterior and posterior margins of the right lobe of the thyroid are widely negative.

[page 2 of 3]
Status of thyroid gland away from tumor: non-neoplastic goiter with cystic degeneration and chronic thyroiditis

Lymph nodes: see previous specimens

Intraoperative Consult Diagnosis:
A frozen section was requested.

FSA1: Parathyroid gland, right inferior
- One lymph node with no evidence of malignancy

FSB1: Parathyroid, right superior
- Normocellular parathyroid tissue

FSC1: Parathyroid, left superior
- Normocellular parathyroid tissue

FSD1: Left cricoid thyroid
- Positive for malignancy consistent with involvement by papillary thyroid carcinoma

Frozen Section Pathologist:

Clinical History:
papillary thyroid cancer.

Gross Description:
Received are seven appropriately labeled containers.

Container A: Received fresh for frozen section and labeled "right inferior parathyroid" is a less than 0.1 gram, 2 x 2 x 2 mm pink/tan soft tissue fragment; block FSA1, .

Container B: Received fresh for frozen section and labeled "right superior parathyroid" is a less than 0.1 gram, 2 x 3 x 2 mm pink/tan soft tissue fragment; block FSB1.

Container C: Received fresh for frozen section and labeled "left superior parathyroid" is a less than 0.1 gram, 2 x 2.5 x 2 mm red/tan soft tissue fragment; block FSC1,

Container D is additionally labeled "left cricoid muscle." It holds a 1.4 x 0.6 x 0.2 cm irregularly shaped fragment of cauterized red/tan soft tissue; block FSD1, NTR.

Container E is additionally labeled "left neck, Level 2-4." It holds a 6.4 x 4.2 x 1.6 cm aggregate of cauterized lobulated yellow/tan fibrofatty tissue containing lymph node candidates up to 1.3 cm in greatest dimension.

E1 - eight lymph node candidates
E2 - five lymph node candidates
E3 - one lymph node candidate, bisected
E4 - one lymph node candidate, bisected
E5 - one lymph node candidate (largest), sectioned

Container F is additionally labeled "left neck Level 6." It holds a 3.4 x 2.5 x 1.2 cm aggregate of cauterized yellow/tan fibrofatty tissue containing lymph node candidates up to 1 cm in greatest dimension.

[page 3 of 3]
F1 - four lymph node candidates
F2,F3 - remainder of fat,

Container G:

Specimen fixation: formalin

Type of specimen: total thyroidectomy

Size and weight of specimen: 22.9 gram; left lobe: 3.5 x 3.2 x 0.8 cm, right lobe: 4.5 x 3.3 x 2.7 cm; centrally attached by an isthmus remarkable for a 1.9 x 0.4 x 0.2 cm pyramidal lobe

Orientation: There is a long suture present on the left lobe. The anterior surface is marked blue, the posterior surface is marked black and the isthmus marked yellow.

Tumor location: in the left lobe, medial aspect

Tumor description: solid, centrally calcified, yellow/tan with ill-defined borders

Tumor size: 2.5 x 1.7 x 1.2 cm

Confinement/non-confinement to the thyroid gland: The tumor extends to blue and black inked surgical margin and is questionably confined to the gland.

Distance of tumor from surgical margins: less than 0.1 cm from the blue anterior inked margin and black posterior inked margin; focally approaches the isthmus

Appearance of thyroid gland away from tumor: dark red/brown; the right lobe of the thyroid is remarkable for a 2.5 x 2.5 x 2.0 cm unilocular thin walled cyst containing tan liquid; the lining of the cyst is smooth, white/tan and glistening; the remaining right lobe is dark red/brown and grossly unremarkable

Tissue submitted for special investigations: yes; Tumor and normal are given to Tissue procurement

Lymph nodes: submitted separately

Digital photograph taken:

Block Summary:

(Inking: anterior/blue, posterior/black, isthmus/yellow)

G1 - superior tip, left lobe

G2-G8 - left lobe, superior towards inferior, respectively (G6 contains relationship to isthmus and pyramidal lobe)

G9-G15 - right thyroid, superior towards inferior respectively,

Light Microscopy:

Light microscopic examination is performed by

Signature

Attending Pathologist:

I have personally conducted the evaluation of the above specimens and have rendered the above diagnosis(es)

Source: NCI Genomic Data Commons file d1a8b3e8-0138-4c3a-9586-fdc6b221c34d (TCGA-DE-A0Y3.1D87503D-1F7D-4545-B579-EF9426B02B5A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).